TCGA case TCGA-B5-A1MU — Uterine Corpus Endometrial Carcinoma (TCGA-UCEC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Corpus uteri; Tissue source site: Duke. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f5261330-596e-4632-a5a3-8d3a2aa5de38

Demographics
Sex at birth: female; Race: white; Country of residence at enrollment: United States; Age at index: 79 years; Vital status: Dead; Days to death: 1,548 days (4.2 years).

Diagnoses (2)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C54.1; Tissue or organ of origin: Endometrium; Site of resection or biopsy: Endometrium; Classification of tumor: primary; Age at diagnosis: 79.5 years (29,027 days); Year of diagnosis: 2006; Method of diagnosis: Biopsy; FIGO stage: Stage IVB; FIGO staging edition year: 1988; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes; Percent tumor invasion: 100.
   Pathology details: Lymph node involved site: Pelvis, NOS; Lymph nodes tested: 0.
   Pathology details: Lymph node involved site: Aortic; Lymph nodes tested: 0.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Tamoxifen; Treatment intent type: Adjuvant; Days to treatment start: 1,399 days (3.8 years); Days to treatment end: 1,550 days (4.2 years); Number of cycles: 1; Prescribed dose: 20; Prescribed dose units: mg/day; Route of administration: Oral.
   Treatment given: Treatment type: Surgery, Open; Initial disease status: Initial Diagnosis.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Tamoxifen; Timepoint category: Prior to Diagnosis.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Subsequent primary of the breast (histology not recorded by GDC). Age at diagnosis: 83.2 years (30,392 days); Days to diagnosis: 1,365 days (3.7 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Initial Diagnosis.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis.
   Recorded as not given: Radiation Therapy, NOS, for initial diagnosis.

Follow-up (2 entries)
- Days to follow up: 1,548 days (4.2 years); Disease response: With Tumor.
- Peritoneal washing results: Positive; Timepoint: Initial Diagnosis.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Menopause status: Postmenopausal; Number of pregnancies: 3; Pregnancy outcome: Full Term Birth, NOS.
- Timepoint category: Initial Diagnosis; Weight: 44 kg; Height: 147 cm; BMI: 20.4.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-B5-A1MU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 260 mg.
  Slide TCGA-B5-A1MU-01A-01-TSA: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 15; Percent lymphocyte infiltration: 8; Percent monocyte infiltration: 3; Percent neutrophil infiltration: 3.
- Sample TCGA-B5-A1MU-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-B5-A1MU-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); History neoadjuvant treatment: No; Tumor status: With tumor; Submitted tumor site: Endometrial; Histologic diagnosis: Serous endometrial adenocarcinoma; Method initial path diagnosis: Office Endometrial Biopsy; Surgical approach at diagnosis: open.
- Follow-up form: History tamoxifen use: Former User; Hypertension diagnosis: No; Diabetes diagnosis indicator: No; Pregnancies full term count: 3; History colorectal cancer: No; Tumor status: With tumor; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Progressive Disease; New tumor event diagnosis indicator: Yes; New tumor event site other: Breast; New tumor event type: New Primary Tumor; New tumor event surgery: Yes; New tumor event surgery days to met: 1374; New tumor event procedure: Surgical Resection; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes.
- Drug treatment: Regimen number: 1.
- Drug treatment, Route of administrations: Route of administration: PO.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,548 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,548 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 1,365 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-B5-A1MU-01A-11D-A13J-01): tumor purity 0.25, ploidy 2.15, whole-genome doublings 0.
